Somatic mutation profile of tumor specimen TCGA-HD-7831-01A (aliquot TCGA-HD-7831-01A-11D-2129-08) from TCGA case TCGA-HD-7831, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,334 days).
Specimen TCGA-HD-7831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8359204e-76a2-4429-81b4-24844e712037.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-7831-10A (Blood Derived Normal), aliquot TCGA-HD-7831-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74ef057e-56f4-44a9-9551-5863761ff962

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.643dup p.S215Kfs*7 | Frame Shift Ins (INS) | VAF 19/53 reads (36%) | catalogued as rs1567551402; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DENND4A | c.5003A>T p.H1668L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV101475437; called by muse, mutect2, varscan2
- FAM193A | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.406); catalogued as rs752257303, COSV100219595; called by muse, mutect2, varscan2
- FBN3 | c.6703G>A p.V2235I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs754675590, COSV54459546; called by muse, mutect2, varscan2
- IQGAP3 | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100752134, COSV100752384; called by muse, mutect2, varscan2
- IQGAP3 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs765276279, COSV63248936; called by muse, mutect2, varscan2
- LBP | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs1179478330, COSV54140714, COSV99028030; called by muse, mutect2
- MYO7A | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV101289270; called by muse, mutect2, varscan2
- NARS2 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs769118312, COSV55251482; called by muse, mutect2, varscan2
- OR8J1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57319246; called by muse, mutect2, varscan2
- PLCH1 | c.1811T>A p.L604* (on ENST00000340059 / NM_001130960.2; = p.L616* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV100398284; called by muse, mutect2, varscan2
- PTH1R | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs758673796, COSV57314701; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- RPIA | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52168803; called by muse, varscan2
- RPS6KA2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761917338, COSV55825803; called by muse, mutect2, varscan2
- RSU1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs200148474, COSV61709234; called by muse, mutect2, varscan2
- RXFP3 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs748753459, COSV100347805; called by muse, mutect2, varscan2
- SEMA4D | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100358826; called by muse, mutect2
- SLC12A7 | c.151C>G p.P51A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99370593; called by muse, mutect2, varscan2
- SOCS6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV101205873; called by muse, mutect2, varscan2
- SP4 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.935); catalogued as COSV99755073; called by muse, mutect2, varscan2
- SPEF2 | c.3619A>G p.R1207G | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100608908; called by muse, mutect2, varscan2
- SYNE1 | c.20272A>T p.I6758L (on ENST00000367255 / NM_182961.4; = p.I6687L on NM_033071.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99579169; called by muse, mutect2, varscan2
- TOPBP1 | c.1906C>G p.P636A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99605864; called by muse, mutect2, varscan2
- ZNF85 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100060154, COSV60216031; called by muse, mutect2
- RASA1 | c.2219_2230del p.A740_H743del | In Frame Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- TTC7B | c.1437_1440dup p.S481Vfs*7 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- TUBA3E | c.1288_1290del p.K430del | In Frame Del (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.901_909del p.Y301_D303del | In Frame Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel
- ANKRD24 | c.3066A>T p.T1022= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV99518161; called by muse, mutect2, varscan2
- CDO1 | c.150C>T p.Y50= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs998550921, COSV99164776; called by muse, mutect2, varscan2
- CPNE6 | c.963G>A p.R321= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99393779; called by muse, mutect2, varscan2
- IGKV1-6 | c.150C>A p.G50= | Silent (SNP) | VAF 33/171 reads (19%) | catalogued as rs766955449; called by muse, mutect2, varscan2
- IQCE | c.1302C>T p.C434= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs533844835, COSV58077669, COSV58078866; called by muse, mutect2, varscan2
- OR52J3 | c.486C>G p.V162= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100984943; called by muse, mutect2, varscan2
- PIGG | c.1399C>T p.L467= (on ENST00000453061 / NM_001127178.3; = p.L459= on NM_017733.4) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99574357; called by muse, mutect2, varscan2
- SLC26A4 | c.543A>G p.R181= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99707531; called by muse, varscan2
- UBR5 | c.5793G>A p.E1931= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as rs1198967112, COSV99642424; called by muse, mutect2, varscan2
- FUT7 | chr9:137035034 C>T | 5'Flank (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21072C>G | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
